Gene-level copy-number profile of tumor specimen TCGA-A2-A0EQ-01A from TCGA case TCGA-A2-A0EQ, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 64.5 years (23,543 days).
Specimen TCGA-A2-A0EQ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.7b6fada0-555f-4234-9436-a498d03e7413.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-A2-A0EQ-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 821 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/756360b8-c928-4bdb-8fca-543cb51102b4

Most common (modal) total copy number across autosomal genes: 5 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 2,522; copy number 3: 6,955; copy number 4: 15,426; copy number 5: 14,295; copy number 6: 11,464; copy number 7: 2,971; copy number 8: 3,274; copy number 9: 1,024; copy number 10: 288; copy number 11: 220; copy number 12: 161; copy number 13: 187; copy number 14: 162; copy number 15: 249; copy number 17: 94; copy number 18: 4; copy number 19: 181; copy number 20: 11; copy number 21: 151; copy number 22: 54; copy number 24: 4; copy number 25: 9; copy number 26: 5; copy number 27: 31; copy number 29: 57; copy number 41: 3.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-A2-A0EQ-01A-11D-A036-01): tumor purity 0.38, ploidy 2.66, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 11, i.e. more than twice the modal value of 5; autosomes only): 1,544 genes in 15 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:70,688,532–81,334,418, 170 genes, copy number 14–27 (broad region; genes not listed).
- chr7:54,933,699–55,862,755, 28 genes, copy number 17–26: AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2, AC073347.1, LANCL2, VOPP1, AC099681.1, AC099681.3, AC099681.2, CDC42P2, TUBBP6, AC091812.1, FKBP9P1, RNU6-389P, Metazoa_SRP, SUMO2P3, CICP11, AC091812.3, AC091812.2, PSPHP1, RNU6-1126P, SEPTIN14, AC092647.4, CICP12, AC092647.3.
- chr7:57,402,181–57,837,046, 29 genes, copy number 19: AC237221.2, AC237221.1, MIR3147, VN1R28P, SAPCD2P2, ZNF716, AC092175.1, NCOR1P3, AC064862.6, AC064862.7, BSNDP4, AC064862.1, AC064862.5, AC064862.2, AC064862.4, AC064862.3, AC023141.4, AC023141.8, AC023141.5, AC023141.12, AC023141.2, AC023141.9, AC023141.11, AC023141.3, AC023141.1, AC023141.10, AC023141.6, AC023141.7, AC023141.13.
- chr8:48,193,850–71,815,625, 341 genes, copy number 11–15 (broad region; genes not listed).
- chr8:83,912,713–101,492,499, 302 genes, copy number 11–17 (broad region; genes not listed).
- chr8:101,528,723–101,562,488, 2 genes, copy number 13: AP001207.2, AP001207.1.
- chr8:141,207,166–143,384,221, 71 genes, copy number 14–22 (broad region; genes not listed).
- chr10:43,778,946–43,901,004, 1 gene, copy number 14 (within-gene range 9–14): LINC00840.
- chr10:43,900,874–45,315,608, 39 genes, copy number 14: LINC02659, LINC00841, AL139237.1, AL137026.2, AL137026.1, LINC02881, AL137026.3, CXCL12, RPL9P21, AL356157.2, AL356157.3, AL356157.1, TMEM72-AS1, EIF2AP4, AL353801.2, TMEM72, AL353801.1, AL353801.3, RASSF4, DEPP1, ZNF22-AS1, ZNF22, CEP164P1, AL358394.3, DUXAP4, RPS19P7, RSU1P2, CUBNP3, AL358394.2, ANKRD54P1, ANKRD30BP3, MIR3156-1, AL358394.1, AL512324.3, AL512324.6, RNU6-1207P, CUBNP2, OR6D1P, OR13A1.
- chr11:68,870,664–70,075,469, 37 genes, copy number 21: LINC02701, MRPL21, IGHMBP2, AP000808.1, MRGPRD, AP003071.4, AP003071.3, MRGPRF, MRGPRF-AS1, TPCN2, AP003071.5, MIR3164, AP003071.1, AP003071.2, SMIM38, MYEOV, IFITM9P, AP005233.2, AP005233.1, AP000439.2, AP000439.1, AP000439.3, LINC02747, LINC01488, CCND1, LTO1, FGF19, DNAJB6P5, FGF4, FGF3, AP007216.1, AP007216.2, AP003555.2, AP003555.1, LINC02753, LINC02584, RNU6-1175P.
- chr11:72,216,601–83,423,516, 265 genes, copy number 13–41 (broad region; genes not listed).
- chr11:83,643,602–83,815,263, 3 genes, copy number 13: DLG2-AS2, AP002370.1, LDHAL6DP.
- chr14:20,468,954–22,483,069, 161 genes, copy number 12 (broad region; genes not listed).
- chr14:23,469,689–26,208,424, 91 genes, copy number 15–27 (within-gene range 9–27) (broad region; genes not listed).
- chr14:44,392,531–44,567,467, 4 genes, copy number 18: AL161752.1, LINC02277, FSCB, AL356022.1.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
